Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3GU, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3GU-01A (Primary Tumor).

UUID: 2D5EF0A8-ASA1-4C28-A723-F2127A834AB6

History Case Pathology Report

Department of Pathology,

Tel: i

DOB:

Sex: F

Physician:

Received:

Pathologist:

Accession:

Case type: Surgical History

**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to the section "SPECIMEN" may have been added. ****

DIAGNOSIS

(A) LEFT THYROID LOBE, EXCISION:

MICROSCOPIC FOCUS OF PAPILLARY THYROID CARCINOMA. (SEE COMMENT)

(B) THYROID, COMPLETION THYROIDECTOMY AND RIGHT NECK DISSECTION WITH RIGHT PARATRACHEAL AND SUPERIOR MEDIASTINAL CONTENTS:

PAPILLARY THYROID CARCINOMA, 5.0 CM.

PAPILLARY THYROID CARCINOMA EXTENDS INTO EXTRATHYROIDAL SOFT TISSUES.

METASTATIC PAPILLARY THYROID CARCINOMA IN 10 OF 23 LYMPH NODES WITH EXTRACAPSULAR EXTENSION (10/23).

Entire report and diagnosis completed by:

Report released by:

COMMENT

In specimen A (left thyroid lobe) a single focus of papillary thyroid carcinoma is identified adjacent to vessels and adipose tissue. This may be continuous with the main tumor mass.

GROSS DESCRIPTION

(A) LEFT THYROID LOBE - A segment of thvroid tissue 2.0 x 1.5 x 1.0 cm. Submitted entirely under A1 and A2.

(B) TOTAL THYROIDECTOMY, RIGHT NECK DISSECTION AND RIGHT PARATRACHEAL SUPERIOR MEDIASTINAL CONTENTS - An oblong hard mass and attached skeletal muscle and fibrovascular tissue with overall measurement of 8.0 x 6.0 x 1.5 cm. The mass measures 5.0 x 3.5 x 2.5 cm. There is no gross involvement of the surrounding fibrous and soft tissue and the mass is light-tan and firm. Representative sections are submitted under B1-B12. The neck contents containing numerous lymph nodes ranging in size from 2.0 cm to 0.4 cm. Multiple grossly positive lymph nodes were noted. The lymph nodes were submitted as B13, _____; B14, 2 lymph nodes; B15, probable four lymph nodes; B16, 3 lymph nodes; B17, 2 lymph nodes; B18, 2 lymph nodes; B19, 3 lymph nodes; B20, two lymph nodes; B21, B22, representative section of the large lymph node.

SNOMED CODES

M-80503 T-B6000

ICD-0-3

carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9 lw 11/30/11

Source: NCI Genomic Data Commons file 5673a5d8-7b45-4f0b-b3ce-deb1dc67cc44 (TCGA-EL-A3GU.2D5EF0A8-A5A1-4C28-A723-F2127A834AB6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).